Gene-level copy-number profile of tumor specimen C3N-02971-01 from CPTAC case C3N-02971, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 78.4 years (28,635 days).
Specimen C3N-02971-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 14fc58dd-f1be-4420-977a-2d7c2c5392da.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02971-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/190ee12c-1446-4a82-bdba-15d1ef3001d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,431; copy number 2: 43,292; copy number 3: 992; copy number 4: 477; copy number 5: 79; copy number 6: 28; copy number 7: 4; copy number 10: 69; copy number 12: 30.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 210 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:96,118,647–100,615,384, 151 genes, copy number 5–12 (broad region; genes not listed).
- chr18:22,413,599–24,708,542, 51 genes, copy number 5: CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57.
- chr19:58,551,566–58,605,223, 8 genes, copy number 5: CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.

Autosomal genes at a single copy (total copy number 1): 12,263. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
